Gene-level copy-number profile of tumor specimen MP2PRT-PAPRGC-TBP1-A from MP2PRT case MP2PRT-PAPRGC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,092 days).
Specimen MP2PRT-PAPRGC-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 473b5116-c315-4382-a427-918a83d4590c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPRGC-NM1-A (blood derived cancer - bone marrow, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,731 have no estimate.
https://portal.gdc.cancer.gov/files/e7581a89-ea15-4f52-8d4d-132ad7f8a0a5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 324; copy number 1: 1,157; copy number 2: 57,071; copy number 3: 340.

Homozygous deletions (total copy number 0; autosomes only): 324 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,661,212–89,661,353, 1 gene (within-gene range 0–2): AC093423.1.
- chr1:198,777,861–198,937,471, 3 genes (within-gene range 0–1): MIR181A1HG, MIR181B1, MIR181A1.
- chr2:88,857,161–89,310,144, 43 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38.
- chr3:18,345,377–18,445,588, 2 genes (within-gene range 0–3): SATB1, AC144521.1.
- chr3:25,664,873–25,664,939, 1 gene (within-gene range 0–1): MIR4442.
- chr3:35,650,197–35,651,961, 1 gene (within-gene range 0–1): ARPP21-AS1.
- chr5:88,717,117–88,904,257, 1 gene (within-gene range 0–2): MEF2C.
- chr5:124,734,618–124,735,175, 1 gene (within-gene range 0–1): AC113398.2.
- chr5:143,375,628–143,375,883, 1 gene (within-gene range 0–1): AC091925.2.
- chr6:26,114,873–26,172,802, 6 genes (within-gene range 0–2): H2BC4, H2AC6, H1-4, H2BC5, AL353759.1, LARP1P1.
- chr6:106,360,717–106,572,017, 1 gene (within-gene range 0–2): CRYBG1.
- chr7:38,239,580–38,340,998, 16 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV6.
- chr7:105,013,425–105,014,321, 1 gene (within-gene range 0–1): KMT2E-AS1.
- chr9:21,349,835–22,128,103, 32 genes: IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr9:71,862,452–71,911,193, 2 genes: ABHD17B, Y_RNA.
- chr10:96,292,685–96,306,695, 1 gene (within-gene range 0–2): AL136181.1.
- chr12:25,004,342–25,108,334, 4 genes (within-gene range 0–2): IRAG2, CENPUP2, AC023510.1, AC023510.2.
- chr12:92,140,278–92,226,557, 4 genes (within-gene range 0–2): BTG1, AC025164.1, RPL21P106, Y_RNA.
- chr12:93,569,814–93,583,487, 1 gene (within-gene range 0–1): SOCS2.
- chr12:115,957,905–116,277,693, 6 genes (within-gene range 0–2): MED13L, AC012157.2, RNU6-1188P, MIR620, SNRPGP18, AC130895.1.
- chr13:40,931,924–41,061,440, 2 genes (within-gene range 0–2): ELF1, RGS17P1.
- chr13:46,374,401–46,374,590, 1 gene (within-gene range 0–1): RNU2-6P.
- chr14:22,483,004–22,513,998, 25 genes (within-gene range 0–2): TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32, TRAJ31, TRAJ30, TRAJ29.
- chr14:61,681,041–61,748,259, 2 genes (within-gene range 0–1): HIF1A-AS1, HIF1A.
- chr14:105,672,308–106,762,588, 160 genes (within-gene range 0–2) (broad region; genes not listed).
- chr17:31,303,770–31,321,749, 3 genes (within-gene range 0–2): EVI2B, AC134669.1, EVI2A.
- chr21:15,050,189–15,067,837, 2 genes (within-gene range 0–2): AF127577.6, AF127577.5.
- chr21:38,502,445–38,502,621, 1 gene (within-gene range 0–2): SNRPGP13.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 409. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
